Gene-level copy-number profile of tumor specimen TCGA-24-2036-01A from TCGA case TCGA-24-2036, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 50.9 years (18,582 days).
Specimen TCGA-24-2036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8e634032-9206-4635-a1d9-faeaef6c3fbb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2036-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/495f35a7-c3ec-41e2-a5c0-9c2536eacf40

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 11,396; copy number 2: 43,604; copy number 3: 3,877; copy number 4: 533; copy number 5: 340.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2036-01): tumor purity 0.94, ploidy 1.91, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,630,825–88,851,844, 66 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 340 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,992,182–227,520,619, 236 genes, copy number 5 (broad region; genes not listed).
- chr6:18,522,735–25,056,664, 80 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:16,849,957–19,002,416, 24 genes, copy number 5 (within-gene range 3–5): AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1.

Autosomal genes at a single copy (total copy number 1): 11,396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
